Gene-level copy-number profile of tumor specimen TCGA-D8-A1XZ-01A from TCGA case TCGA-D8-A1XZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 81.9 years (29,916 days).
Specimen TCGA-D8-A1XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6eb5b047-3e90-4a41-8082-46a74c008a90.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ea5ce183-553e-4acb-ab61-570f69382bb0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 767; copy number 2: 13,893; copy number 3: 24,500; copy number 4: 14,843; copy number 5: 2,659; copy number 6: 562; copy number 7: 437; copy number 8: 357; copy number 9: 229; copy number 10: 302; copy number 11: 686; copy number 12: 70; copy number 13: 108; copy number 15: 88; copy number 16: 50; copy number 17: 34; copy number 19: 107; copy number 20: 50; copy number 27: 51; copy number 33: 17; copy number 37: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XZ-01A-11D-A14J-01): tumor purity 0.66, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,589 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,595,414–18,748,866, 2 genes, copy number 7 (within-gene range 4–7): AL031737.1, PAX7.
- chr1:24,502,351–24,844,321, 9 genes, copy number 8 (within-gene range 3–8): RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P.
- chr1:202,590,596–205,943,460, 116 genes, copy number 12–19 (broad region; genes not listed).
- chr1:206,865,354–206,970,625, 7 genes, copy number 20: IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR.
- chr5:94,111,720–99,595,297, 92 genes, copy number 8 (broad region; genes not listed).
- chr7:144,048,948–145,681,369, 35 genes, copy number 7 (within-gene range 5–7): OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1.
- chr7:147,378,017–152,436,003, 143 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr7:156,668,946–157,269,370, 14 genes, copy number 8 (within-gene range 6–8): LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1.
- chr8:55,449,509–57,592,451, 43 genes, copy number 8 (within-gene range 6–8): SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1.
- chr8:64,798,804–145,066,685, 1,257 genes, copy number 7–37 (broad region; genes not listed).
- chr14:22,867,818–24,335,093, 108 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr15:44,956,687–52,709,817, 192 genes, copy number 7–27 (broad region; genes not listed).
- chr17:19,215,615–19,336,715, 1 gene, copy number 11 (within-gene range 3–11): EPN2.
- chr17:19,296,596–29,707,090, 317 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:29,639,627–29,645,847, 3 genes, copy number 11: AC104564.1, RNU6-920P, AC104564.5.
- chr17:48,103,357–56,914,080, 215 genes, copy number 11–13 (within-gene range 2–13) (broad region; genes not listed).
- chr19:94,062–409,147, 21 genes, copy number 11: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG, AC010641.2, AC010641.1, C2CD4C.
- chr22:16,933,521–17,165,445, 14 genes, copy number 17: IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1.

Autosomal genes at a single copy (total copy number 1): 767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
